TCGA case TCGA-98-8020 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - Alabama. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ffb53b81-c1ed-473c-bdcd-b325b02e22ae

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 84 days.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.2 years (20,509 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 56.2 years (20,520 days); Days to diagnosis: 11 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 11 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 11 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 84 days; Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Other clinical attributes
- DLCO (% of predicted): 47; FEV1/FVC before bronchodilator (%): 77; FEV1 before bronchodilator (% of reference): 79.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-98-8020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-98-8020-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-98-8020-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-98-8020-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-98-8020-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 1.1; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS mutation found: No; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder; Other malignancy histological type: High grade urothelial carcinoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -392.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy bladder cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 84 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 84 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 11 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-98-8020-01A-11D-2243-01): tumor purity 0.46, ploidy 3.17, whole-genome doublings 1.
